Surgical pathology report (de-identified scan), TCGA case TCGA-76-4934, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4934-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Suboccipital tumor consistent with glioblastoma: GLIOBLASTOMA, GRADE iv OF iv (who SCALE), SEE MICROSCOPIC DESCRIPTION, SEE COMMENT
2. Suboccipital tumor consistent with glioblastoma: GLIOBLASTOMA, GRADE iv OF iv (who SCALE), SEE MICROSCOPIC DESCRIPTION, SEE COMMENT

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of an infiltrative proliferation of moderately to markedly pleomorphic astrocytes. There are foci containing multinucleated tumor giant cells. There is abundant microvascular proliferation, numerous mitoses, and pseudopalisading necrosis. The findings are diagnostic of a glioblastoma, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

1. Suboccipital tumor consistent with glioblastoma: Glioblastoma

[page 2 of 5]
[REDACTED]

Clinical History and Diagnosis:
Brain tumor

Source of Specimen:

- 1: Suboccipital tumor consistent with glioblastoma
- 2: Suboccipital tumor consistent with glioblastoma

Gross Description:

[REDACTED]

1. Suboccipital tumor consistent with glioblastoma: Received fresh is a fragment of soft tan tissue measuring 1.5 x 1.3 x 0.3 cm.

Approximately 50% of the specimen is used for touch preparation and frozen section diagnosis (cassette A.). The remainder of the specimen is submitted in one additional cassette.

2. Suboccipital tumor consistent with glioblastoma: Received in formalin are multiple fragments of soft tan-pink tissue measuring 1.3 x 1.0 x 0.4 cm in aggregate. The specimen is entirely submitted in one cassette.

Histology Laboratory
H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer' s recommendation.

Documented by [REDACTED]
[REDACTED]

[page 3 of 5]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED] Hospital.

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 4 of 5]
[REDACTED]
Patient: [REDACTED]

MEDICAL GENETICS REPORT

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENT IN-SITU
HYBRIDIZATION
(FISH)

RESULT: Negative for the deletion of 1p
Negative for the deletion of 19q

NOMENCLATURE:nuc ish 1p36(P73 x1 ~4),1q24(ANGPTL1 x1
~ 3)[200]/19p13(ZNF44 x1 ~4),19q13(GLTSCR x1 ~4)[200]

1p36/1q24

Number of Nuclei scored: 200

Ratio of 1p/1q: 1.00

% cells with del 1p: 9%

19q13/19p13

Number of Nuclei scored: 200

Ratio of 19q/19p: 0.97

% cells with del 19q: 0.5%

INTERPRETATION: The results are within the normal range and suggest
absence of deletions of 1p and 19q in this suboccipital tumor

[REDACTED] del (1p) and del(19q) has been observed in glioma
specimens, especially oligodendrogliomas. Clinical and pathologic
correlation is recommended.

Comment:

[REDACTED]

[REDACTED]
Report Electronically Signed on [REDACTED]

[page 5 of 5]
[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Data Analysis:

DESCRIPTION OF THE ASSAY: 1p and 19q FISH studies were performed on paraffin embedded tumor sections. Two hybridizations were performed: one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the [REDACTED]

[REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration.

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file 4785c762-7f01-4002-8cb9-12b3b73e28e0 (TCGA-76-4934.31727BD3-2AF9-4648-B5AE-60AF7BE49EA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).